Somatic mutation profile of tumor specimen MP2PRT-PAUCPZ-TMP1-A (aliquot MP2PRT-PAUCPZ-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUCPZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,028 days).
Specimen MP2PRT-PAUCPZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1cf24c0-4d21-4b1b-91cb-4e6f8f7e511e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCPZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCPZ-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/717cedaf-99f5-4c08-a3a9-be017a7ab055

The open-access MAF lists 96 somatic variants for this specimen: 78 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 15, Nonsense Mutation 11, Intron 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 74/143 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.1783G>A p.E595K (on ENST00000304032 / NM_001037131.3; = p.E542K on NM_014914.5) | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs1012518397; called by muse, mutect2, varscan2
- ANXA1 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99973820; called by muse, mutect2, varscan2
- ATXN2L | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV57379388; called by muse, mutect2
- BSN | c.1621G>C p.V541L | Missense Mutation (SNP) | VAF 298/598 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56527168; called by muse, mutect2, varscan2
- C2CD5 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 101/128 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142421095; called by muse, mutect2, varscan2
- CCDC171 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1385226804; called by muse, mutect2, varscan2
- CTCF | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 131/289 reads (45%) | catalogued as COSV50474326; called by muse, mutect2, varscan2
- DHX16 | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 173/424 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs17189232; called by muse, varscan2
- DHX16 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 298/702 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as rs746785622, COSV64565959; called by muse, mutect2, varscan2
- EBNA1BP2 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 82/386 reads (21%) | catalogued as COSV99356126; called by muse, mutect2, varscan2
- EFCAB3 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); catalogued as COSV59504002; called by muse, mutect2, varscan2
- FLG | c.5360G>C p.G1787A | Missense Mutation (SNP) | VAF 146/341 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.833); catalogued as CD072423; called by muse, mutect2, varscan2
- FLT4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs747487993, COSV56097066; called by muse, varscan2
- GRIA1 | c.2328G>C p.L776F | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53604206; called by muse, mutect2
- H6PD | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771839732; called by muse, mutect2, varscan2
- HDLBP | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 136/325 reads (42%) | catalogued as rs1225518003, COSV60491846; called by muse, mutect2, varscan2
- HECTD4 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.8); catalogued as rs780374124, COSV61180689; called by muse, mutect2, varscan2
- KAT6A | c.3116C>G p.S1039C | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55906104, COSV55909869; called by muse, mutect2, varscan2
- KCNA4 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 168/373 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs372809586; called by muse, mutect2, varscan2
- NLRP12 | c.3085C>T p.L1029F | Missense Mutation (SNP) | VAF 116/271 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60755410; called by muse, mutect2, varscan2
- PSAP | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as rs774816225; called by muse, mutect2, varscan2
- PTPN2 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV58995751; called by muse, mutect2, varscan2
- PTPN7 | c.925C>T p.Q309* (on ENST00000495688; = p.Q348* on NM_002832.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 178/417 reads (43%) | catalogued as COSV100460204; called by muse, mutect2, varscan2
- RHOXF1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 158/184 reads (86%) | SIFT tolerated (0.43); PolyPhen benign (0.26); catalogued as COSV99483866; called by muse, mutect2, varscan2
- RUSC1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 132/557 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs756488918, COSV52738402; called by muse, mutect2, varscan2
- SH2D3A | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 341/786 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as rs1362326927; called by muse, mutect2, varscan2
- SIGLEC12 | c.1675G>C p.E559Q (on ENST00000291707 / NM_053003.4; = p.E441Q on NM_033329.2) | Missense Mutation (SNP) | VAF 162/421 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as COSV52460273; called by muse, mutect2, varscan2
- SMG1 | c.9760G>C p.E3254Q | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs752001043; called by muse, mutect2, varscan2
- STXBP5 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs138457066; called by muse, mutect2, varscan2
- TBC1D21 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs753261741, COSV55995351; called by muse, mutect2, varscan2
- TDRD5 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs113046765; called by muse, mutect2, varscan2
- TMEM128 | c.133C>T p.L45F (on ENST00000382753 / NM_001297552.2; = p.L21F on NM_032927.3) | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1006656011; called by muse, mutect2
- TOMM34 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV65689696; called by muse, mutect2, varscan2
- TUBGCP5 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.164); catalogued as rs755058797; called by muse, mutect2, varscan2
- WFDC6 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 98/244 reads (40%) | catalogued as rs553341164, COSV60549073; called by muse, mutect2
- ZNF467 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 357/781 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57373806; called by muse, mutect2, varscan2
- ACACB | c.5870T>G p.I1957S | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADH4 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- ARMH4 | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- ATXN2L | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- BTLA | c.771T>A p.Y257* | Nonsense Mutation (SNP) | VAF 161/362 reads (44%) | called by muse, mutect2, varscan2
- CBL | c.2701C>G p.P901A | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR1 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 173/554 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CEP192 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CUL9 | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CYP4F2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DEF6 | c.1812G>C p.Q604H | Missense Mutation (SNP) | VAF 181/429 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- GORASP1 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HIBCH | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGSF21 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ITIH3 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KDM4C | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- KDM6B | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 25/454 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.067); called by muse, mutect2
- LAYN | c.683-1G>A p.X228_splice (on ENST00000375615 / NM_001258390.1; = p.X220_splice on NM_178834.5) | Splice Site (SNP) | VAF 21/315 reads (7%) | called by muse, mutect2
- LMAN1 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- LRRC9 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MFSD13A | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 132/362 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MTMR9 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- MTMR9 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.311); called by muse, mutect2
- MTTP | c.1934G>C p.R645T | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NBEAL1 | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NOL11 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PVR | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RHEBL1 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOJ | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 183/463 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RIBC2 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, varscan2
- SAP30BP | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 202/418 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SEC24D | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SLC30A8 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 142/357 reads (40%) | called by muse, mutect2, varscan2
- SMIM35 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- THSD1 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 183/412 reads (44%) | called by muse, mutect2, varscan2
- TNK1 | c.1275G>T p.Q425H (on ENST00000576812 / NM_001251902.2; = p.Q420H on NM_003985.5) | Missense Mutation (SNP) | VAF 25/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TOPBP1 | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TUB | c.698C>G p.S233* (on ENST00000299506 / NM_177972.3; = p.S288* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 112/268 reads (42%) | called by muse, mutect2, varscan2
- WDR19 | c.2553G>C p.E851D | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ZNF736 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ZZEF1 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 68/312 reads (22%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1479C>T p.L493= | Silent (SNP) | VAF 52/722 reads (7%) | catalogued as rs767540243, COSV51439318; called by muse, mutect2
- CALHM5 | c.576C>T p.F192= | Silent (SNP) | VAF 110/330 reads (33%) | called by muse, mutect2, varscan2
- CCDC102A | c.1212G>A p.L404= | Silent (SNP) | VAF 224/481 reads (47%) | catalogued as rs768756848; called by muse, mutect2, varscan2
- COL6A3 | c.7626C>T p.F2542= | Silent (SNP) | VAF 80/354 reads (23%) | catalogued as rs758039484, COSV55110469; called by muse, mutect2, varscan2
- GEMIN5 | c.3081C>T p.L1027= | Silent (SNP) | VAF 134/340 reads (39%) | catalogued as rs755253452; called by muse, mutect2, varscan2
- HTR5A | c.363C>T p.D121= | Silent (SNP) | VAF 251/554 reads (45%) | catalogued as rs778025705, COSV55286591, COSV55286853; called by muse, mutect2, varscan2
- LAMB3 | c.2526C>T p.F842= | Silent (SNP) | VAF 86/281 reads (31%) | called by muse, mutect2, varscan2
- LIN54 | c.132G>A p.L44= | Silent (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- LOXHD1 | c.1767C>G p.L589= | Silent (SNP) | VAF 14/434 reads (3%) | called by muse, mutect2
- LRP5 | c.1407G>A p.V469= | Silent (SNP) | VAF 117/309 reads (38%) | catalogued as rs1404758320, COSV99592617; called by muse, mutect2, varscan2
- SH2D3A | c.1371G>A p.L457= | Silent (SNP) | VAF 171/412 reads (42%) | called by muse, mutect2, varscan2
- SLC12A9 | c.438C>T p.V146= | Silent (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- TRPM6 | c.723C>G p.L241= | Silent (SNP) | VAF 137/368 reads (37%) | called by muse, mutect2, varscan2
- UBR4 | c.2280C>A p.L760= | Silent (SNP) | VAF 153/325 reads (47%) | called by muse, mutect2, varscan2
- ZFP36 | c.246C>T p.F82= (on ENST00000594442; = p.F76= on NM_003407.5) | Silent (SNP) | VAF 293/682 reads (43%) | catalogued as rs1361442372, COSV50527908, COSV99953984; called by muse, mutect2, varscan2
- AKNAD1 | c.2167+171G>C | Intron (SNP) | VAF 140/363 reads (39%) | catalogued as rs963225966; called by muse, mutect2, varscan2
- KIR3DX1 | n.746G>A | RNA (SNP) | VAF 103/288 reads (36%) | catalogued as rs779318173, COSV55596494; called by muse, mutect2, varscan2
